Surgical pathology report (de-identified scan), TCGA case TCGA-IR-A3LH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IR-A3LH-01A (Primary Tumor).

[page 1 of 3]
Specimens Submitted:

- 1: SP: Right periaortic lymph node (fs)
- 2: SP: Left para-aortic lymph nodes (fs)
- 3: SP: Posterior vaginal margin (fs)
- 4: SP: Radical hysterectomy with bilateral tubes and ovaries (fs)
- 5: SP: Right external iliac lymph node
- 6: SP: Right external iliac lymph node, lateral
- 7: SP: Right common iliac lymph node (
- 8: SP: Right obturator lymph node
- 9: SP: Right hypogastric lymph node
- 10: SP: Left external iliac lymph nodes (
- 11: SP: Left common iliac lymph node
- 12: SP: Left obturator lymph node
- 13: SP: Left hypogastric lymph node...
- 14: SP: Left parametrium (

DIAGNOSIS:

- 1) LYMPH NODES, RIGHT PERIAORTIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- ENDOSALPINGIOSIS INVOLVES ONE LYMPH NODE.
- 2) LYMPH NODE, LEFT PARA-AORTIC; EXCISION:
- ONE BENIGN LYMPH NODE WITH ENDOSALPINGIOSIS (0/1).
- 3) VAGINA, POSTERIOR MARGIN; EXCISION:
- INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED.
- ULCER IS PRESENT IN PROXIMAL PORTIONS OF THIS TISSUE.
- THE TUMOR IS PRESENT AT THE LEFT LATERAL DISTAL MARGIN.

NOTE: WE CONFIRM THAT THE MARGIN SAMPLED AT THE TIME OF FROZEN SECTION WAS BENIGN. [REDACTED] WAS CONTACTED ABOUT THIS BY EMAIL ON [REDACTED]

- 4) UTERUS, CERVIX, BILATERAL OVARIES AND TUBES, BILATERAL PARAMETRIUM; RADICAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- INVASIVE SQUAMOUS CELL CARCINOMA OF UTERINE CERVIX, POORLY DIFFERENTIATED/UNDIFFERENTIATED.

** Continued on next page **

100-0-3
carcinoma, squamous cell 8070/3
Site: cervix, NOS C53.9
lw
12/20/11

[page 2 of 3]
[REDACTED]

- TUMOR THICKNESS IS 8 MM OUT OF 12 MM.
- NO EVIDENCE OF TUMOR MULTICENTRICITY IS IDENTIFIED.
- IN SITU CARCINOMA IS ALSO PRESENT.
- NO VASCULAR INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- VAGINAL EXTENSION IS PRESENT (SEE NOTE).
- NO PARAMETRIAL INVOLVEMENT IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE ENDOMETRIUM IS UNREMARKABLE.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ADENOMYOSIS.
- THE RIGHT OVARY SHOWS SEROUS CYSTADENOMA.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): SEVEN BENIGN RIGHT PARAMETRIAL LYMPH NODES (0/7).
- INCIDENTAL ADRENAL REST AND OCCLUDED BLOOD VESSELS IDENTIFIED IN RIGHT PARAMETRIUM.

NOTE: THE POSTERIOR VAGINAL CUFF MARGIN OF THIS SPECIMEN IS EXTENSIVELY ULCERATED AND INFLAMED. ALTHOUGH DEFINITE INVASIVE CARCINOMA IS NOT IDENTIFIED DISTALLY IN THIS SPECIMEN, WE NOTE THAT INVASIVE CARCINOMA IS PRESENT IN THE ADDITIONAL POSTERIOR MARGIN (PART 3).

- 5) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
- 6) LYMPH NODES, RIGHT EXTERNAL ILIAC, LATERAL; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 7) LYMPH NODES, RIGHT COMMON ILIAC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 8) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 9) LYMPH NODE, RIGHT HYPOGASTRIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 10) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 11) LYMPH NODES, LEFT COMMON ILIAC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 12) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
- ENDOSALPINGIOSIS INVOLVING ONE LYMPH NODE.
- 13) LYMPH NODE, LEFT HYPOGASTRIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 14) PARAMETRIUM, LEFT; EXCISION:
- BENIGN FIBROCONNECTIVE TISSUE.
- ONE BENIGN LYMPH NODE (0/1).

** Continued on next page **

[page 3 of 3]
7

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Source: NCI Genomic Data Commons file 3e272e47-9c95-4c8c-bb65-194742b1c72e (TCGA-IR-A3LH.7204DF29-2167-48A0-AA56-51E9AFFBB0D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).